Somatic mutation profile of tumor specimen TCGA-J1-A4AH-01A (aliquot TCGA-J1-A4AH-01A-31D-A24D-08) from TCGA case TCGA-J1-A4AH, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.9 years (25,893 days).
Specimen TCGA-J1-A4AH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9eef93ce-eadc-4010-89a5-2f8929e0e091.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J1-A4AH-10A (Blood Derived Normal), aliquot TCGA-J1-A4AH-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a06d8321-4867-437a-bc09-1f9e04a9b22f

The open-access MAF lists 197 somatic variants for this specimen: 154 protein-altering or splice-affecting, 41 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 41, Nonsense Mutation 9, Frame Shift Del 2, Splice Site 2, In Frame Del 1, RNA 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 35/75 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA3 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM068733, CM120578, COSV57050344; called by muse, mutect2, varscan2
- ABCC4 | c.3021G>A p.M1007I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100972750, COSV65316952; called by muse, mutect2, varscan2
- ADAMTS19 | c.3301G>T p.D1101Y | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99180370; called by muse, mutect2, varscan2
- AGO1 | c.998del p.K333Sfs*7 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as COSV64596282; called by mutect2, pindel, varscan2
- ARHGAP9 | c.2107C>T p.R703C (on ENST00000393797 / NM_001319850.2; = p.R684C on NM_032496.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs764230374, COSV57360138; called by muse, mutect2, varscan2
- ARMCX1 | c.915G>C p.Q305H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100863236; called by muse, mutect2, varscan2
- ASAP2 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99856732; called by muse, mutect2, varscan2
- ATXN10 | c.729-1G>C p.X243_splice | Splice Site (SNP) | VAF 20/104 reads (19%) | catalogued as COSV53294084, COSV99426696; called by muse, mutect2, varscan2
- B2M | c.311A>G p.H104R | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs781076330, COSV100837701; called by muse, mutect2, varscan2
- BRINP3 | c.1388G>A p.C463Y | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV100819372; called by muse, mutect2, varscan2
- C19orf54 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.737); catalogued as COSV54574988; called by muse, mutect2, varscan2
- C5AR2 | c.927G>T p.W309C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.513); catalogued as COSV99953886; called by muse, mutect2, varscan2
- CABS1 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1021253739, COSV99909178; called by muse, mutect2, varscan2
- CASR | c.2747C>T p.T916M (on ENST00000490131; = p.T993M on NM_000388.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs758227966, COSV56136619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC127 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 21/130 reads (16%) | catalogued as COSV99723137; called by muse, mutect2, varscan2
- CDH10 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100052942; called by muse, mutect2, varscan2
- CDH10 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779300580, COSV52597547; called by muse, mutect2, varscan2
- CDH3 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99869057; called by muse, mutect2, varscan2
- CENPF | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100871934; called by muse, mutect2, varscan2
- CEP162 | c.2632C>T p.R878W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374739713; called by muse, mutect2, varscan2
- CHD7 | c.6122C>A p.S2041Y | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV101418409, COSV71115607; called by muse, mutect2, varscan2
- CLEC18A | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99847036; called by muse, mutect2
- CNTN5 | c.3282G>A p.M1094I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV54346419; called by muse, mutect2
- COIL | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.294); catalogued as rs772183772, COSV99538369; called by muse, mutect2, varscan2
- COL14A1 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV99920491; called by muse, mutect2, varscan2
- CRB1 | c.1191C>A p.D397E | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV100958066, COSV66329251; called by muse, mutect2, varscan2
- CUX1 | c.2861A>G p.E954G | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52900003; called by muse, mutect2
- DIAPH3 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99934407; called by muse, mutect2
- DNAJB1 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs770760423, COSV99584249; called by muse, mutect2, varscan2
- DNM1L | c.1565G>A p.R522K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.079); catalogued as COSV99846410; called by muse, mutect2, varscan2
- DSCAM | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs577827734, COSV68630908; called by muse, mutect2
- DSG3 | c.1269C>T p.V423= | Splice Region (SNP) | VAF 17/81 reads (21%) | catalogued as COSV99934670; called by muse, mutect2, varscan2
- EIF4E | c.578T>C p.I193T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV99794947; called by muse, mutect2, varscan2
- EPB41L4A | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1297860020, COSV54870840, COSV99814038; called by muse, mutect2, varscan2
- EPHA7 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as COSV100994278; called by muse, mutect2, varscan2
- ESYT2 | c.2011C>G p.Q671E (on ENST00000613624; = p.Q595E on NM_020728.3) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.125); catalogued as rs1282076640, COSV99277209; called by muse, mutect2, varscan2
- EXOSC4 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs782316494, COSV100284196; called by muse, mutect2, varscan2
- EYA3 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100870290; called by muse, mutect2, varscan2
- F13B | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100803421; called by muse, mutect2, varscan2
- FAM47B | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV100264584; called by muse, mutect2, varscan2
- FAT1 | c.6693C>A p.F2231L | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101499623; called by muse, mutect2, varscan2
- FAT2 | c.9836T>G p.L3279R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99943997; called by muse, mutect2, varscan2
- FBN1 | c.2434G>C p.E812Q | Missense Mutation (SNP) | VAF 99/204 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV100354635, COSV100356282; called by muse, mutect2, varscan2
- FBXL19 | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100609341; called by muse, mutect2
- FCRL3 | c.1974C>A p.S658R | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV100943516; called by muse, mutect2, varscan2
- FILIP1L | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100497320; called by muse, mutect2
- H1-0 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV99959924; called by muse, mutect2, varscan2
- HTR1F | c.964T>C p.C322R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1485978669, COSV100138288; called by muse, mutect2, varscan2
- IGHV3-21 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.308); catalogued as rs1555459113; called by muse, mutect2, varscan2
- IGLV6-57 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101135320; called by muse, mutect2, varscan2
- INPP4B | c.1603A>G p.I535V | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99526517; called by muse, mutect2, varscan2
- IPO8 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.071); catalogued as COSV56245803, COSV99805625; called by muse, mutect2, varscan2
- IPP | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100739699; called by muse, mutect2, varscan2
- KCNG1 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs758172905, COSV100856938; called by muse, mutect2, varscan2
- KCNN1 | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99716300; called by muse, mutect2
- KCNV1 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.998); catalogued as rs756504582, COSV52084851; called by muse, mutect2, varscan2
- KDM5B | c.740A>G p.E247G | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV99351342; called by muse, mutect2
- KMT2A | c.5374G>C p.A1792P | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100628881, COSV100629716; called by muse, mutect2, varscan2
- KMT2A | c.5375C>T p.A1792V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV100629718; called by muse, mutect2, varscan2
- LARGE1 | c.1299G>T p.Q433H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as rs1463323644, COSV100506260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDB2 | c.357C>G p.D119E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV100454687, COSV58768140; called by muse, mutect2, varscan2
- LILRB1 | c.1042G>T p.D348Y (on ENST00000427581; = p.D312Y on NM_006669.6) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100207817; called by muse, mutect2, varscan2
- MAGEC1 | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs777733607, COSV53580455, COSV99596431; called by muse, mutect2, varscan2
- MEAK7 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs762756945, COSV100640451, COSV59143865; called by muse, mutect2, varscan2
- MKNK2 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV99170396; called by muse, mutect2, varscan2
- MMP16 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99689784; called by muse, mutect2, varscan2
- MOV10 | c.1625T>C p.V542A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.18); catalogued as COSV100659759; called by mutect2, varscan2
- MPZL1 | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100850316; called by muse, mutect2, varscan2
- MTHFD2 | c.763+2T>A p.X255_splice | Splice Site (SNP) | VAF 70/138 reads (51%) | catalogued as rs757096061, COSV99903189; called by muse, mutect2, varscan2
- MUC16 | c.24482C>G p.S8161C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as rs751167703, COSV101201379; called by muse, mutect2, varscan2
- MYH10 | c.3173G>C p.R1058T | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99346193; called by muse, mutect2, varscan2
- MYH15 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56304185, COSV99844178; called by muse, mutect2, varscan2
- MYH9 | c.3677G>T p.R1226L | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as rs200697030, COSV53385328; called by muse, mutect2
- MYOZ3 | c.231C>A p.S77R | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99770873; called by muse, mutect2, varscan2
- NLRP11 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as rs116279591, COSV64086582; called by muse, mutect2, varscan2
- NLRP3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs141906483; called by muse, mutect2, varscan2
- NLRP5 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as rs577761633, COSV66761737; called by muse, mutect2, varscan2
- NRK | c.4421T>C p.L1474P | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99689022; called by muse, mutect2, varscan2
- NUP188 | c.1547G>A p.G516D | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101001482; called by muse, mutect2, varscan2
- NYNRIN | c.2186G>A p.G729D | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV101230688; called by muse, mutect2
- OR10G8 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs149526223; called by muse, mutect2, varscan2
- OR10K2 | c.807C>A p.S269R | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100149650; called by muse, mutect2, varscan2
- OR2AE1 | c.365G>C p.R122P | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100318388; called by muse, mutect2, varscan2
- OR4E2 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100330148; called by muse, mutect2, varscan2
- OR4P4 | c.275A>T p.Y92F | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.905); catalogued as rs746442650, COSV100111843; called by muse, mutect2, varscan2
- OR5D18 | c.902C>A p.T301K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV100450873; called by muse, mutect2, varscan2
- OR8J3 | c.337A>T p.M113L | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100041005; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.464C>G p.S155C (on ENST00000259318 / NM_001136562.3; = p.S386C on NM_007203.5) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99395662; called by muse, mutect2, varscan2
- PAPOLA | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs1335213161, COSV99354581; called by muse, mutect2, varscan2
- PCDH15 | c.5513C>A p.T1838K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as COSV100226864; called by muse, varscan2
- PCDH7 | c.3080C>A p.A1027D | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.899); catalogued as COSV100688609; called by muse, mutect2
- PCLO | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.758); catalogued as COSV100437103; called by muse, mutect2
- POLG | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99175036; called by muse, varscan2
- PPM1J | c.1415C>T p.T472I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1251582521, COSV99588485; called by muse, mutect2, varscan2
- PPOX | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.041); catalogued as COSV99237740; called by muse, mutect2, varscan2
- PRKG1 | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100914548, COSV64835496; called by mutect2, varscan2
- PRKRIP1 | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV100700356; called by muse, mutect2, varscan2
- PROS1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | catalogued as COSV100820203; called by muse, mutect2, varscan2
- PSME4 | c.2524A>C p.S842R | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV101122628; called by muse, mutect2, varscan2
- PTDSS1 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1453664601, COSV100428918; called by muse, mutect2, varscan2
- PTP4A3 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as rs147441142; called by muse, mutect2, varscan2
- RANBP17 | c.1675A>G p.T559A | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101206372; called by muse, mutect2, varscan2
- REV1 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754921264, COSV99301423; called by muse, mutect2, varscan2
- RNF20 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.971); catalogued as COSV101206578; called by muse, mutect2
- RSAD2 | c.1012T>G p.F338V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101150021; called by muse, mutect2, varscan2
- SEC24D | c.2644C>G p.Q882E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.815); catalogued as COSV54881422, COSV99756731; called by muse, mutect2, varscan2
- SGIP1 | c.1354C>A p.P452T | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99392747; called by muse, mutect2, varscan2
- SH2B3 | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); catalogued as COSV100374504; called by muse, mutect2, varscan2
- SIDT1 | c.1542A>G p.I514M | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1243362907, COSV99334610; called by muse, mutect2, varscan2
- SLC30A3 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV51987017, COSV99273840; called by muse, mutect2, varscan2
- SLC7A13 | c.685G>C p.G229R | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99879173; called by muse, mutect2, varscan2
- SRP72 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs1276394666, COSV100714371; called by muse, mutect2, varscan2
- SRRM2 | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV57075506; called by muse, mutect2, varscan2
- TAF4 | c.2708C>G p.S903* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99434947; called by muse, mutect2, varscan2
- TARS2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.039); catalogued as COSV100946092; called by muse, mutect2, varscan2
- TAT | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.273); catalogued as COSV63533815; called by muse, mutect2, varscan2
- TELO2 | c.1367C>G p.S456C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.428); catalogued as COSV99248675; called by muse, mutect2, varscan2
- TIAM2 | c.1274A>T p.Q425L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as COSV100019986; called by muse, mutect2, varscan2
- TICRR | c.3671C>G p.S1224C | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99179591; called by muse, varscan2
- TIMP1 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319834840, COSV99512283; called by muse, mutect2, varscan2
- TMEM132D | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs1253234057, COSV70595621; called by muse, mutect2, varscan2
- TMEM145 | c.1397C>T p.T466I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.014); catalogued as rs1377782523, COSV99238777; called by muse, mutect2, varscan2
- TMPRSS15 | c.911T>G p.I304R | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99519184; called by muse, mutect2, varscan2
- TRIM37 | c.424A>G p.K142E | Missense Mutation (SNP) | VAF 7/203 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs1177966587, COSV99233394; called by muse, mutect2
- TRIM44 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100195537; called by muse, mutect2, varscan2
- TRIP12 | c.5905T>G p.S1969A | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99390872; called by muse, mutect2, varscan2
- TSKU | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100290230; called by muse, mutect2, varscan2
- TTC24 | c.893A>G p.K298R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.153); catalogued as COSV100964363; called by muse, mutect2, varscan2
- TTC29 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100284477; called by muse, mutect2, varscan2
- TUBGCP2 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs745574797, COSV53304112; called by muse, mutect2, varscan2
- TUBGCP6 | c.3079G>C p.G1027R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99956238; called by muse, mutect2, varscan2
- TUT7 | c.2159A>T p.H720L | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.011); catalogued as COSV99463552; called by muse, mutect2, varscan2
- UROD | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272375360, COSV99870427; called by muse, mutect2, varscan2
- VPS13B | c.3914C>T p.S1305F | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100663409; called by muse, mutect2
- WDR11 | c.2375G>A p.R792K | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs757483816, COSV99676942; called by muse, mutect2, varscan2
- WDR17 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs370197137; called by muse, mutect2, varscan2
- WDR17 | c.1721G>T p.W574L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99708186; called by muse, mutect2, varscan2
- XDH | c.1210C>G p.L404V | Missense Mutation (SNP) | VAF 103/212 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.897); catalogued as COSV101052447; called by muse, varscan2
- XDH | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV101052451; called by muse, varscan2
- XRCC1 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99486732; called by muse, mutect2
- ZDHHC12 | c.510G>T p.W170C | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387455581, COSV99403898; called by muse, mutect2, varscan2
- ZFHX4 | c.1315A>T p.K439* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99266914; called by muse, mutect2, varscan2
- ZNF263 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV54596131; called by muse, mutect2, varscan2
- ZNF319 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV99540446; called by muse, mutect2, varscan2
- ZNF443 | c.1256G>A p.G419E | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100042347, COSV56894039; called by muse, mutect2, varscan2
- ZNF471 | c.500G>T p.C167F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100340816; called by muse, mutect2, varscan2
- ZNF638 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100039828; called by muse, mutect2, varscan2
- ZNF711 | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.023); catalogued as COSV99340881, COSV99341539; called by muse, mutect2, varscan2
- NLRP4 | c.361del p.L121Yfs*31 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | called by mutect2, pindel, varscan2
- PABPC3 | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- TRAV9-1 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- XRCC5 | c.2043_2054del p.D681_L685delinsE | In Frame Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.2520T>C p.V840= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs767558611; called by muse, mutect2, varscan2
- AHNAK | c.2787G>A p.L929= | Silent (SNP) | VAF 7/182 reads (4%) | catalogued as COSV99949369; called by muse, mutect2
- ATP2A2 | c.2826C>A p.L942= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV100428869; called by muse, mutect2, varscan2
- CBX4 | c.264T>C p.R88= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99490554; called by muse, mutect2, varscan2
- CNGA3 | c.1170G>C p.L390= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99737376; called by muse, mutect2, varscan2
- DIAPH2 | c.2778G>A p.L926= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as rs891070455, COSV100235020; called by muse, mutect2, varscan2
- DNAH7 | c.10284A>G p.A3428= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV100417218; called by muse, mutect2, varscan2
- DRD2 | c.648C>T p.L216= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV100670103; called by muse, mutect2, varscan2
- DSCAM | c.2967G>A p.Q989= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV101260097, COSV101261408; called by muse, mutect2, varscan2
- ESX1 | c.312C>G p.L104= | Silent (SNP) | VAF 44/79 reads (56%) | catalogued as COSV101006504; called by muse, mutect2, varscan2
- GALNT7 | c.612A>G p.E204= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99397761; called by muse, mutect2, varscan2
- GDF6 | c.241C>A p.R81= | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as COSV99748503; called by muse, mutect2, varscan2
- GMCL1 | c.1080C>G p.L360= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs571177119, COSV99247916; called by muse, mutect2, varscan2
- GRM7 | c.2328G>A p.K776= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100738301; called by muse, mutect2, varscan2
- H3C13 | c.132C>A p.P44= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV58944282; called by muse, mutect2, varscan2
- KCNN1 | c.675C>T p.D225= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1267217144, COSV99716298; called by muse, mutect2, varscan2
- KCTD10 | c.558T>A p.I186= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV99949411; called by muse, mutect2, varscan2
- MRS2 | c.42G>T p.A14= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV99219116; called by muse, mutect2, varscan2
- MTHFSD | c.630C>T p.V210= (on ENST00000360900 / NM_001159377.2; = p.V209= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100530533; called by muse, mutect2, varscan2
- MUC17 | c.954G>T p.T318= | Silent (SNP) | VAF 107/320 reads (33%) | catalogued as rs775661782, COSV60285545; called by muse, mutect2, varscan2
- NFE2L2 | c.828A>G p.T276= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV101229431; called by muse, mutect2, varscan2
- NLRP12 | c.2145G>A p.L715= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100145827; called by muse, mutect2, varscan2
- OR6Q1 | c.300T>C p.D100= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs776369205, COSV100110464; called by muse, mutect2, varscan2
- PKHD1 | c.1875G>T p.L625= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs886038725, COSV100584415; ClinVar: likely benign; called by muse, mutect2, varscan2
- POTEF | c.2409C>A p.V803= | Silent (SNP) | VAF 56/171 reads (33%) | catalogued as COSV100665309; called by muse, mutect2, varscan2
- PPP2R5D | c.849C>T p.I283= | Silent (SNP) | VAF 23/154 reads (15%) | catalogued as rs913774986, COSV99776537, COSV99776632; called by muse, mutect2, varscan2
- SDHD | c.435C>T p.H145= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs200062830, COSV100978965; ClinVar: likely benign; called by muse, mutect2, varscan2
- SGIP1 | c.345G>A p.K115= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99392742; called by muse, mutect2, varscan2
- SPARCL1 | c.402C>G p.L134= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV99215853; called by muse, mutect2, varscan2
- SPATA31D1 | c.507G>T p.S169= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV100783027, COSV61200978; called by muse, mutect2, varscan2
- SRCAP | c.1734A>C p.L578= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as COSV99351193; called by muse, mutect2, varscan2
- TICRR | c.3744C>G p.L1248= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs759463753, COSV99179593; called by muse, varscan2
- TMC7 | c.561C>G p.L187= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs750959539, COSV100432786, COSV58583671; called by muse, mutect2, varscan2
- TMIGD2 | c.813G>A p.P271= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as rs745975486, COSV100010497; called by muse, mutect2, varscan2
- TSHZ3 | c.1356C>T p.F452= | Silent (SNP) | VAF 42/199 reads (21%) | catalogued as COSV99552561; called by muse, mutect2, varscan2
- UNC93A | c.1176C>G p.A392= | Silent (SNP) | VAF 22/149 reads (15%) | catalogued as COSV100023630; called by muse, mutect2, varscan2
- VBP1 | c.534G>A p.R178= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV99660984; called by muse, mutect2
- XDH | c.1164C>G p.T388= | Silent (SNP) | VAF 86/180 reads (48%) | catalogued as COSV101052449; called by muse, varscan2
- ZAN | c.4230C>A p.G1410= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100770280; called by muse, mutect2, varscan2
- ZBTB7A | c.237C>T p.F79= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1180902049, COSV100475914; called by muse, mutect2, varscan2
- ZNF83 | c.589A>C p.R197= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV99991542; called by muse, mutect2
- TTBK2 | c.823-6940C>T | Intron (SNP) | VAF 48/102 reads (47%) | catalogued as rs753966462; called by muse, varscan2
- UBTFL2 | n.135C>G | RNA (SNP) | VAF 20/269 reads (7%) | called by muse, mutect2
